Somatic mutation profile of tumor specimen TCGA-AA-3855-01A (aliquot TCGA-AA-3855-01A-01W-0995-10) from TCGA case TCGA-AA-3855, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 72.7 years (26,541 days).
Specimen TCGA-AA-3855-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0e91ecf-248f-4d68-b2c9-436255f9f2b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3855-10A (Blood Derived Normal), aliquot TCGA-AA-3855-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/481d4607-eb24-44e6-a61c-f8de14259467

The open-access MAF lists 149 somatic variants for this specimen: 106 protein-altering or splice-affecting, 41 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 41, Nonsense Mutation 11, Frame Shift Del 3, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXCR4 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs104893624, CM030831, COSV54010080; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV101036616; called by muse, mutect2, varscan2
- ACVR1C | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1336118698, COSV54643912; called by muse, mutect2, varscan2
- AGL | c.3216G>C p.E1072D | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.335); catalogued as CD104353, COSV99648594; called by muse, mutect2
- AK5 | c.192G>T p.K64N (on ENST00000354567 / NM_174858.3; = p.K38N on NM_012093.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV58354884; called by muse, mutect2, varscan2
- AKR1B10 | c.856A>C p.M286L | Missense Mutation (SNP) | VAF 28/710 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV100610146; called by muse, mutect2
- ATP2A3 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1158996937, COSV59226705; called by muse, varscan2
- ATP8A2 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 171/869 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745650033, COSV54942586; called by muse, mutect2, varscan2
- BAZ2A | c.1880C>T p.T627M | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs559867064, COSV99464904; called by muse, mutect2, varscan2
- BCO1 | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as rs570126506, COSV99257495; called by muse, mutect2, varscan2
- BDP1 | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100702793; called by muse, mutect2, varscan2
- BRINP3 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as COSV100818427; called by muse, mutect2, varscan2
- CCAR1 | c.1399C>G p.L467V | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); catalogued as COSV56267454; called by muse, mutect2, varscan2
- CCDC39 | c.159T>G p.N53K | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.084); catalogued as COSV99867545; called by muse, varscan2
- CCR1 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 24/524 reads (5%) | catalogued as rs1258275945, COSV56122337; called by muse, mutect2
- CDK14 | c.1030C>T p.R344* (on ENST00000380050 / NM_001287135.2; = p.R326* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 159/645 reads (25%) | catalogued as rs1441195365, COSV56033578; called by muse, mutect2, varscan2
- CNTN1 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751030; called by muse, mutect2, varscan2
- COL24A1 | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100992980; called by muse, mutect2
- COL5A2 | c.3065C>G p.T1022S | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.084); catalogued as COSV100880046; called by muse, mutect2
- DAPK1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774238093, COSV100801179; called by muse, mutect2, varscan2
- DCAF4 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1221331475, COSV62319026; called by muse, mutect2, varscan2
- DEUP1 | c.954G>T p.L318F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99976727; called by muse, mutect2
- DICER1 | c.1216C>T p.Q406* | Nonsense Mutation (SNP) | VAF 18/115 reads (16%) | catalogued as COSV100601820; called by muse, mutect2, varscan2
- FAM126A | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 113/278 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV101327060; called by muse, mutect2, varscan2
- FAM163B | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1434110234, COSV63203275; called by mutect2, varscan2
- FAM71D | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100315123; called by muse, mutect2
- FAT3 | c.6186T>A p.H2062Q | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.166); catalogued as COSV53078674; called by muse, mutect2, varscan2
- FGF13 | c.190C>A p.H64N | Missense Mutation (SNP) | VAF 113/196 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0.046); catalogued as COSV101002723; called by muse, mutect2, varscan2
- FGR | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142690351; called by muse, mutect2, varscan2
- GIGYF1 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99308902; called by muse, mutect2
- GPRC5C | c.269G>A p.R90H (on ENST00000652232; = p.R45H on NM_018653.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs551384896, COSV61239393; called by muse, mutect2, varscan2
- GRIK4 | c.1672G>T p.V558F | Missense Mutation (SNP) | VAF 183/553 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101483474; called by muse, mutect2, varscan2
- HOXA11 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50052834; called by muse, mutect2, varscan2
- IFNAR1 | c.1114A>G p.I372V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as COSV99531491; called by muse, mutect2, varscan2
- IRAK2 | c.1619C>T p.S540F | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV56528879; called by muse, mutect2, varscan2
- KANSL1 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 32/101 reads (32%) | catalogued as COSV52267578; called by muse, mutect2, varscan2
- KCNQ3 | c.2500G>A p.A834T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772240164, COSV66463681; called by muse, mutect2, varscan2
- KIF26B | c.4204C>T p.R1402W | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.328); catalogued as rs184020024; called by muse, mutect2, varscan2
- KLHL13 | c.441A>T p.K147N | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.036); catalogued as COSV99451126; called by muse, mutect2
- KLHL13 | c.439A>C p.K147Q | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as COSV53251330, COSV99451146; called by muse, mutect2
- KLK15 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs1474255058, COSV100032553; called by muse, mutect2, varscan2
- LIFR | c.2059G>T p.E687* | Nonsense Mutation (SNP) | VAF 89/372 reads (24%) | catalogued as COSV54684326; called by muse, mutect2, varscan2
- LRFN2 | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 89/442 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV100599174; called by muse, mutect2, varscan2
- LRRC4C | c.466C>T p.R156* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV53426135; called by muse, mutect2, varscan2
- LYG1 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100415875, COSV57915186; called by muse, mutect2, varscan2
- MDN1 | c.16307A>C p.H5436P | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101020847; called by muse, mutect2, varscan2
- MIA3 | c.5654G>C p.R1885T | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100388071, COSV60512600; called by muse, mutect2, varscan2
- MIPOL1 | c.1204G>T p.E402* | Nonsense Mutation (SNP) | VAF 38/119 reads (32%) | catalogued as COSV59379810; called by muse, mutect2, varscan2
- MOV10L1 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as rs752711170, COSV53167220, COSV53167920; called by muse, mutect2, varscan2
- NARS1 | c.888G>T p.L296F | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754289689, COSV56875920; called by muse, mutect2, varscan2
- NR2F2 | c.517A>T p.N173Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101240934; called by muse, mutect2, varscan2
- NRG4 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs778316625, COSV67529863; called by muse, mutect2, varscan2
- NT5C3A | c.382G>A p.A128T (on ENST00000610140 / NM_001374335.1; = p.A94T on NM_016489.13) | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs772942875, COSV54236925; called by muse, mutect2
- OAS3 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs376430790; called by muse, mutect2, varscan2
- OR1C1 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563143111, COSV68715361; called by muse, mutect2, varscan2
- OR6B3 | c.214T>C p.W72R | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100097303, COSV60112835; called by mutect2, varscan2
- OR9G1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs770433930; called by muse, mutect2
- OTX1 | c.1018T>G p.C340G | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99246188; called by muse, mutect2, varscan2
- PCDH17 | c.2114C>T p.S705L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV64972953; called by muse, mutect2, varscan2
- PCDHA7 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.846); catalogued as COSV65342015; called by muse, mutect2, varscan2
- PCDHA9 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV65334243; called by muse, mutect2
- PCDHB12 | c.2318A>G p.N773S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); catalogued as COSV99506847; called by muse, mutect2, varscan2
- PIM2 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs948485351, COSV55943700; called by muse, mutect2, varscan2
- PLA2G4D | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs757985311, COSV51819198; called by muse, mutect2, varscan2
- PLCG2 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369760877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POT1 | c.98A>G p.K33R | Missense Mutation (SNP) | VAF 29/824 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100714016; called by muse, mutect2
- POU4F2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751460020, COSV55586096; called by muse, mutect2, varscan2
- PRRC2A | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs781324096, COSV101050978; called by muse, mutect2, varscan2
- PUS7 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 328/800 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs143361545; called by muse, mutect2, varscan2
- PWP1 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 137/546 reads (25%) | catalogued as rs199564672, COSV69832417; called by muse, mutect2, varscan2
- RASAL3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99483810; called by muse, varscan2
- RP1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109741, COSV99606467; called by muse, mutect2, varscan2
- RSPO2 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52638484; called by muse, mutect2, varscan2
- SARS2 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV99671154; called by muse, mutect2, varscan2
- SCN9A | c.5656C>T p.R1886W (on ENST00000303354; = p.R1875W on NM_002977.3) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs560168893, COSV57599473; called by muse, mutect2, varscan2
- SETD5 | c.2933G>A p.R978Q | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs756178441, COSV100200247; called by muse, mutect2, varscan2
- SEZ6L | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371478865; called by muse, mutect2, varscan2
- SKP2 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.034); catalogued as COSV57039931; called by muse, mutect2, varscan2
- SLC39A10 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62766347; called by muse, mutect2, varscan2
- SORL1 | c.5767G>A p.V1923I | Missense Mutation (SNP) | VAF 138/513 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs144747223, COSV99492929; called by muse, mutect2, varscan2
- SPATS2 | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100423391, COSV100423741; called by muse, mutect2, varscan2
- ST6GAL2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | PolyPhen probably damaging (0.983); catalogued as rs1193641422, COSV64526161; called by muse, mutect2, varscan2
- ST8SIA3 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | PolyPhen probably damaging (0.998); catalogued as rs761031428, COSV100129359; called by muse, mutect2, varscan2
- SUN2 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781099795, COSV53283414; called by muse, mutect2, varscan2
- TACC1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs368667882; called by muse, mutect2, varscan2
- TIAM2 | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.449); catalogued as COSV100018147; called by muse, mutect2, varscan2
- TNKS | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV60052105, COSV60061633; called by muse, mutect2, varscan2
- TOP2B | c.2157C>A p.F719L (on ENST00000264331 / NM_001330700.2; = p.F714L on NM_001068.3) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51968847; called by muse, mutect2, varscan2
- TRAF5 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373368870; called by muse, mutect2, varscan2
- TRPV6 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1181979039, COSV100844155; called by muse, mutect2, varscan2
- TUBAL3 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs368080202, COSV66814675; called by muse, mutect2, varscan2
- TUFM | c.289_291del p.E97del | In Frame Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs1396667236; called by pindel, varscan2
- UPK1A | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as rs377645091; called by muse, mutect2, varscan2
- USH2A | c.9907G>A p.D3303N | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs1367867781, COSV56339910; called by muse, mutect2, varscan2
- WASF2 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 217/1062 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71004837; called by muse, mutect2, varscan2
- ZBTB21 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as COSV100176941; called by muse, mutect2, varscan2
- ZC3H13 | c.881C>A p.T294K | Missense Mutation (SNP) | VAF 330/1766 reads (19%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.01); catalogued as COSV99667587; called by mutect2, varscan2
- ZFHX4 | c.9791C>T p.P3264L | Missense Mutation (SNP) | VAF 116/409 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99257627; called by muse, mutect2, varscan2
- ZFP64 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 89/613 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.272); catalogued as COSV53801284, COSV99402030; called by muse, mutect2, varscan2
- ZNF292 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 40/774 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV100369911; called by muse, mutect2
- ZNF536 | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1392485761, COSV62820033; called by muse, mutect2, varscan2
- ZNF708 | c.1086A>C p.K362N | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100803045; called by muse, mutect2
- APC | c.4063del p.S1355Lfs*60 | Frame Shift Del (DEL) | VAF 64/121 reads (53%) | called by mutect2, pindel, varscan2
- ARID1A | c.3482del p.K1161Sfs*19 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- HK3 | c.1883G>A p.G628D | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZMYM3 | c.1113del p.G372Vfs*75 | Frame Shift Del (DEL) | VAF 31/58 reads (53%) | called by mutect2, pindel, varscan2
- ABCC3 | c.133C>T p.L45= | Silent (SNP) | VAF 53/491 reads (11%) | catalogued as COSV99558773; called by muse, mutect2, varscan2
- ADGRG4 | c.5605A>C p.R1869= | Silent (SNP) | VAF 16/262 reads (6%) | catalogued as COSV54961513, COSV99794566; called by muse, mutect2
- ALS2 | c.3645C>T p.S1215= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as COSV51883995; called by muse, varscan2
- ATP2B2 | c.3018C>T p.H1006= (on ENST00000352432; = p.H972= on NM_001683.5) | Silent (SNP) | VAF 161/517 reads (31%) | catalogued as rs769667950, COSV59489863; called by muse, mutect2, varscan2
- CAD | c.3339C>T p.S1113= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs146143846; called by muse, mutect2, varscan2
- CDC20B | c.1152C>T p.H384= | Silent (SNP) | VAF 20/272 reads (7%) | catalogued as rs763435648, COSV99696777; called by muse, mutect2
- CEP164 | c.3870G>A p.P1290= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs371367995; called by muse, mutect2, varscan2
- CMTM4 | c.282G>A p.A94= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs376800910; called by muse, mutect2, varscan2
- FBXO8 | c.204C>T p.F68= | Silent (SNP) | VAF 151/603 reads (25%) | catalogued as COSV101183615, COSV67031292; called by muse, mutect2, varscan2
- FLG | c.12093T>C p.Y4031= | Silent (SNP) | VAF 44/235 reads (19%) | catalogued as COSV64236880; called by muse, mutect2, varscan2
- FLRT2 | c.408A>G p.E136= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100420074; called by muse, mutect2
- INTS8 | c.2892A>G p.T964= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV57374982; called by muse, mutect2, varscan2
- KRTAP13-4 | c.288C>A p.G96= | Silent (SNP) | VAF 60/201 reads (30%) | catalogued as COSV61878565; called by muse, mutect2, varscan2
- LARGE1 | c.555C>T p.L185= | Silent (SNP) | VAF 31/488 reads (6%) | catalogued as COSV100504764; called by muse, mutect2
- LMOD2 | c.759C>T p.D253= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as rs746530747, COSV71755619; called by muse, mutect2
- LRRTM1 | c.816G>A p.E272= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99701961; called by muse, mutect2, varscan2
- NCAPD2 | c.3207C>T p.P1069= | Silent (SNP) | VAF 25/186 reads (13%) | catalogued as COSV59697929; called by muse, mutect2, varscan2
- NEK5 | c.1377C>T p.N459= | Silent (SNP) | VAF 156/687 reads (23%) | catalogued as rs752409091, COSV62878944; called by muse, mutect2, varscan2
- NPAP1 | c.879G>A p.P293= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs763751156, COSV61504653, COSV61508807; called by muse, mutect2, varscan2
- NRXN1 | c.336C>T p.G112= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs1043285496, COSV68003239; called by muse, mutect2
- NUP50 | c.561T>C p.F187= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV61660751; called by muse, mutect2, varscan2
- OR1J4 | c.561C>A p.L187= | Silent (SNP) | VAF 44/132 reads (33%) | catalogued as COSV61589590; called by muse, mutect2, varscan2
- OR1L8 | c.489G>A p.L163= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV59185770; called by muse, mutect2, varscan2
- P3H3 | c.1041G>A p.P347= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as rs781817957, COSV51831062; called by muse, mutect2, varscan2
- PCDHB1 | c.1704C>T p.N568= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs137984585, COSV60629843, COSV60631383; called by muse, mutect2, varscan2
- PPP2R2D | c.741G>A p.V247= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV101409023; called by muse, mutect2
- PRKAA1 | c.63G>A p.R21= | Silent (SNP) | VAF 72/237 reads (30%) | catalogued as COSV57183068; called by muse, mutect2, varscan2
- PRR14 | c.1560T>C p.A520= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1451736765, COSV54910817; called by muse, mutect2, varscan2
- PSMD1 | c.864G>A p.P288= | Silent (SNP) | VAF 17/245 reads (7%) | catalogued as rs761346386, COSV58082062; called by muse, mutect2
- RBM14 | c.462G>T p.G154= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs534878980, COSV59557832; called by muse, mutect2
- RPL38 | c.198G>A p.V66= | Silent (SNP) | VAF 65/276 reads (24%) | catalogued as COSV53908739; called by muse, mutect2, varscan2
- RXFP2 | c.1827T>C p.Y609= | Silent (SNP) | VAF 252/1206 reads (21%) | catalogued as COSV53633224; called by muse, mutect2, varscan2
- RXYLT1 | c.786G>A p.L262= | Silent (SNP) | VAF 187/512 reads (37%) | catalogued as rs1420184732, COSV54167593; called by muse, mutect2, varscan2
- SPTA1 | c.6675C>T p.D2225= | Silent (SNP) | VAF 45/370 reads (12%) | catalogued as rs186647435, COSV63749286; called by muse, mutect2, varscan2
- TAAR5 | c.726G>T p.G242= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV57798485; called by muse, mutect2, varscan2
- TAC3 | c.345G>A p.K115= | Silent (SNP) | VAF 111/397 reads (28%) | catalogued as COSV55647839; called by muse, mutect2, varscan2
- TCTE1 | c.594G>A p.P198= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs201345272, COSV65255103; called by muse, varscan2
- TRRAP | c.5766G>A p.Q1922= (on ENST00000359863 / NM_001244580.1; = p.Q1904= on NM_003496.3) | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as COSV100722096; called by muse, mutect2, varscan2
- ZHX1 | c.2484T>C p.G828= | Silent (SNP) | VAF 162/440 reads (37%) | catalogued as COSV52875432; called by muse, mutect2, varscan2
- ZNF233 | c.258G>A p.E86= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV61933252; called by muse, mutect2, varscan2
- ZNF462 | c.2949G>A p.S983= | Silent (SNP) | VAF 51/174 reads (29%) | catalogued as rs199712014, COSV99470959; called by muse, mutect2, varscan2
- MIR1283-1 | n.78G>A | RNA (SNP) | VAF 75/222 reads (34%) | catalogued as rs371239652; called by muse, mutect2, varscan2
- OR2W5 | n.518A>C | RNA (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
